CCDI case PBBHGB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a57f090d-785a-4824-80de-6e902c83fb6a

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Giant cell glioblastoma: ICD-O-3 morphology code: 9441/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.0 years (2,197 days).

Biospecimens (3 samples)
- Sample 0D8E1V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D8E25: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D8E2P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
